Surgical pathology report (de-identified scan), TCGA case TCGA-42-2589, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-42-2589-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN

- A. Omentum
- B. Omentum
- C. No specimen "C" is received in Histology.
- D. Appendix with tumor
- E. Uterus, cervix, bilateral ovaries with tubes, posterior vagina, parametria, rectum
- F. Left pelvic nodes
- G. Right pelvic nodes
- H. Right aortic nodes
- I. Right diaphragm peritoneum

CLINICAL NOTES

PRE-OP DIAGNOSIS: Pelvic mass

FROZEN SECTION DIAGNOSIS

A) Omentum, biopsy: Metastatic non-mucinous carcinoma.

GROSS DESCRIPTION

A. The specimen is received unfixed labelled "portion of omentum" and consists of a white and yellow piece of soft tissue measuring 3 x 3.2 x 1 cm. A portion of specimen is taken for frozen section diagnosis as requested.

B. The specimen is received unfixed labelled "omentum" and consists of two pieces of yellow omentum measuring 30 x 6 x 1 cm. The omentum contains multiple nodules of tumor measuring up to 3 cm in diameter. A portion of specimen is taken for research purposes.

D. The specimen is received in formalin labeled "appendix with tumor" and consists of a white vermiform appendix measuring 5 cm in length and 0.7 cm in diameter. There is adjacent mesoappendix measuring 5.5 x 2.5 x 1.5 cm. There are tumor nodules

[page 2 of 4]
GROSS DESCRIPTION

in the mesoappendix, two obvious gross nodules measure 1 and 2 cm in diameter. This specimen may have been a partially dissected part of my examination.

E. The specimen is received unfixed labeled "uterus, cervix, bilateral ovaries with tubes, parametria, post vagina, rectum" and consists of a uterus with attached right adnexa and probable attached left adnexa and with adherent segment of bowel. There is also a piece of white mucosa-covered tissue that probably represents vagina. This specimen has been partially dissected prior to my examination for research purposes. The uterus

measures 8.5 x 6 x 4.8 cm. The left ovary has been incised prior to my examination. The ovary measures approximately 4 x 2.5 x 2.5 cm. There is some red tissue adjacent to the ovary that might be tubal. The right ovary is white and red and measures 4 x 3.5 x 2.5 cm.

The right ovary has been incised prior to my examination and is adherent to the adjacent segment of bowel. There is stenosis of the external

os. The uterine cavity contains scant tan endometrium. The myometrium is up to 1.7 cm in thickness. On cut section there is tan tumor in both ovaries. The tumor in the right ovary measures 4.5 cm in greatest dimension. The tumor in the left ovary measures 3.3 cm in greatest dimension. The segment of bowel measures 21.5 cm

in length and up to 6 cm in diameter. On closer inspection, there appear to be two segments of bowel that run at right angles to each other but this may be an artifact of the bowel being cut when the tissue was taken for research purposes. One segment measures 17.5 cm in length and the other measures 9.5 cm in length. The shorter segment is immediately behind the vagina and also overlies a nodular

mass of tumor measuring 7 x 7 x 4 cm. This tumor is tan with areas of yellow discoloration and also some areas of cystic degeneration.

F. The specimen is received unfixed, labeled "left pelvic nodes" and consists of a red and yellow piece of soft tissue measuring 1.6 x 1 x 0.6 cm. Bisected.

[page 3 of 4]
GROSS DESCRIPTION

pelvic G. The specimen is received unfixed, labeled "right
nodes" and consists of a disciform piece of yellow and red
soft tissue measuring 4 x 3 x 1 cm.
aortic H. The specimen is received unfixed, labeled "right
node" and consists of a yellow and red piece of soft
tissue
measuring 4 x 2.5 x 1 cm. RS-2
I. The specimen is received unfixed, labeled "right
diaphragm peritoneum" and consists of a rubbery firm piece
of tan-white tissue measuring 7 x 4 x 1 cm.

MICROSCOPIC DESCRIPTION

A., B. Sections of omentum show metastatic nonmucinous
carcinoma with tumor giant cells.
D. Fibrous obliteration of the appendiceal lumen is
present. There is periappendiceal metastatic
carcinoma.
E. Tumor type: Poorly differentiated nonmucinous
carcinoma, compatible with serous carcinoma.
Tumor grade: FIGO grade 3 (out of 3)
Tumor size: Carcinoma measures 4 cm. in greatest
dimension in both ovaries.
Mitotic rate: 64 mitoses/10 HPFs (1 HPF = 0.19 sq
mm).
Extracapsular tumor: Present.
Uterine tube: Bilateral peritubal carcinoma is
present.
pTNM stage: T3c N1
F-I. Microscopic examination performed.

[page 4 of 4]
MICROSCOPIC DESCRIPTION

3x2, 2, 5

DIAGNOSIS

- A., B. Omentum, resection:
Metastatic poorly differentiated serous carcinoma.
- D. Vermiform appendix, resection:
Fibrous obliteration of the appendiceal lumen.
Periappendiceal metastatic carcinoma.
- E. Uterus, bilateral attached adnexa, posterior vagina and
rectum, resection:
Bilateral poorly differentiated serous carcinoma
of
the ovary, with extensive periovarian and
perirectal carcinoma.
- F. Lymph node, left pelvic, biopsy:
Metastatic carcinoma is present in a a single
lymph
node.
- G. Lymph node, right pelvic, biopsy:
Metastatic carcinoma is present in a single lymph
node.
- H. Lymph node, right aorta, biopsy:
There is no evidence of malignancy in any of four
lymph nodes.
- I. Abdominal cavity, right diaphragm, biopsy: Metastatic
carcinoma.
-

Source: NCI Genomic Data Commons file 6cea3eca-9cac-4732-b406-0a89e528f732 (TCGA-42-2589.07CCEB21-4ACA-4343-965E-81960A40CFF2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).